Somatic mutation profile of tumor specimen TCGA-25-1329-01A (aliquot TCGA-25-1329-01A-01W-0492-08) from TCGA case TCGA-25-1329, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 76.9 years (28,093 days).
Specimen TCGA-25-1329-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6193dd8-035d-476a-9992-9f6c7aea37ff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-25-1329-10A (Blood Derived Normal), aliquot TCGA-25-1329-10A-01W-0492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0669fbe7-32c5-49be-9844-96262b69d869

The open-access MAF lists 51 somatic variants for this specimen: 43 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Nonsense Mutation 9, Silent 7, Frame Shift Del 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TTN | c.5047C>T p.R1683* (on ENST00000591111; = p.R1637* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 145/545 reads (27%) | catalogued as rs587780490, COSV59948489; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- AC004593.2 | c.1244A>T p.N415I | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV56094554; called by muse, mutect2, varscan2
- ANGEL1 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV51873876; called by muse, mutect2, varscan2
- ATP9A | c.2770T>G p.F924V | Missense Mutation (SNP) | VAF 19/134 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.755); catalogued as COSV58767935; called by muse, mutect2, varscan2
- CD163L1 | c.2311C>T p.R771* | Nonsense Mutation (SNP) | VAF 32/114 reads (28%) | catalogued as rs766981681, COSV58018107; called by muse, mutect2, varscan2
- CENPQ | c.400T>G p.L134V | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as COSV59921379; called by muse, mutect2, varscan2
- DIO3 | c.464C>T p.A155V | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as rs1302989906, COSV63773725; called by muse, mutect2, varscan2
- DNAI3 | c.96G>C p.E32D | Missense Mutation (SNP) | VAF 25/127 reads (20%) | SIFT tolerated (0.36); PolyPhen benign (0.054); catalogued as COSV54003455; called by muse, mutect2, varscan2
- DSP | c.1891C>T p.Q631* | Nonsense Mutation (SNP) | VAF 12/292 reads (4%) | catalogued as COSV101131274; called by muse, mutect2
- EPHB1 | c.980G>A p.R327H | Missense Mutation (SNP) | VAF 33/203 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as rs747682274, COSV67653214; called by muse, mutect2, varscan2
- FSIP2 | c.18515A>T p.D6172V | Missense Mutation (SNP) | VAF 40/130 reads (31%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.79); catalogued as COSV100555068; called by muse, mutect2, varscan2
- GRIN1 | c.1062G>T p.M354I | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.92); PolyPhen benign (0.015); catalogued as COSV100160237; called by muse, mutect2
- KCNS3 | c.503G>A p.R168Q | Missense Mutation (SNP) | VAF 69/273 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.988); catalogued as rs746908572, COSV100411287, COSV58407461; called by muse, mutect2, varscan2
- KIAA0100 | c.4507A>G p.K1503E | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.978); catalogued as rs1567649737, COSV101197298; called by muse, mutect2
- KIAA1109 | c.10847G>A p.R3616Q | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs764890289, COSV99163151; called by muse, mutect2, varscan2
- KIR3DL3 | c.416C>T p.T139M | Missense Mutation (SNP) | VAF 236/2018 reads (12%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs544733307, COSV52546043; called by muse, mutect2, varscan2
- MFAP3L | c.357C>A p.D119E | Missense Mutation (SNP) | VAF 123/417 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64371877; called by muse, mutect2, varscan2
- MIB1 | c.1567T>G p.L523V | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated (0.44); PolyPhen probably damaging (0.92); catalogued as COSV55091489; called by muse, mutect2, varscan2
- MTOR | c.121G>T p.A41S | Missense Mutation (SNP) | VAF 110/192 reads (57%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as rs758668050, COSV63873045, COSV63877802; called by muse, mutect2, varscan2
- NINJ2 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 34/172 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as rs765113142, COSV56753832; called by muse, mutect2, varscan2
- OR5F1 | c.59C>T p.T20M | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.549); catalogued as rs753933467, COSV53545997; called by muse, mutect2, varscan2
- OSBPL11 | c.1798A>G p.I600V | Missense Mutation (SNP) | VAF 128/340 reads (38%) | SIFT tolerated (0.86); PolyPhen probably damaging (0.987); catalogued as COSV99954172; called by muse, mutect2, varscan2
- PHF21A | c.1791C>A p.C597* (on ENST00000418153 / NM_001101802.3; = p.C551* on NM_016621.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 13/123 reads (11%) | catalogued as COSV99138511; called by muse, mutect2
- PRDM9 | c.1148C>G p.P383R | Missense Mutation (SNP) | VAF 375/1132 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.296); catalogued as rs1286686864, COSV57007946; called by muse, mutect2, varscan2
- PROSER1 | c.1999A>G p.S667G | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.145); catalogued as COSV61488078; called by muse, mutect2, varscan2
- PRPF4 | c.1460T>A p.L487Q (on ENST00000374198 / NM_001322267.2; = p.L488Q on NM_004697.5) | Missense Mutation (SNP) | VAF 123/407 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65252869; called by muse, mutect2, varscan2
- PYGL | c.809G>A p.R270Q | Missense Mutation (SNP) | VAF 35/744 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as rs755488866, COSV53588634; called by muse, mutect2
- RSBN1L | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.007); catalogued as rs375776456, COSV58508906; called by muse, mutect2, varscan2
- SERPINA12 | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 181/628 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs555631497, COSV100369673; called by muse, mutect2, varscan2
- SLC25A51 | c.169C>T p.R57* | Nonsense Mutation (SNP) | VAF 27/142 reads (19%) | catalogued as COSV54253084; called by muse, mutect2, varscan2
- SLC6A18 | c.187G>A p.A63T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs140475239; called by muse, mutect2, varscan2
- STIP1 | c.1566A>T p.L522F | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99656571; called by muse, mutect2, varscan2
- TBX18 | c.805C>T p.R269* | Nonsense Mutation (SNP) | VAF 8/54 reads (15%) | catalogued as COSV63735921; called by muse, mutect2, varscan2
- TMEM132D | c.2671C>T p.Q891* | Nonsense Mutation (SNP) | VAF 64/218 reads (29%) | catalogued as COSV67158768; called by muse, mutect2, varscan2
- TNFRSF10A | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 112/697 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs748872586, COSV55325141, COSV55326118; called by muse, mutect2, varscan2
- TPP2 | c.1489C>T p.Q497* | Nonsense Mutation (SNP) | VAF 17/365 reads (5%) | catalogued as COSV101060261; called by muse, mutect2
- TRAF3IP1 | c.241G>T p.V81L | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV100966862; called by muse, mutect2
- TTN | c.14881G>A p.A4961T (on ENST00000591111; = p.A4034T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 542/1634 reads (33%) | PolyPhen probably damaging (0.998); catalogued as rs754692422, COSV59861214, COSV60157889; called by muse, mutect2, varscan2
- UROD | c.1072C>A p.H358N | Missense Mutation (SNP) | VAF 18/364 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99870171; called by muse, mutect2
- ZRANB2 | c.901A>T p.R301* | Nonsense Mutation (SNP) | VAF 93/215 reads (43%) | catalogued as COSV54672452; called by muse, mutect2, varscan2
- CEACAM18 | c.285_286del p.N95Kfs*14 | Frame Shift Del (DEL) | VAF 151/257 reads (59%) | called by mutect2, pindel, varscan2
- MBD1 | c.1115_1116del p.C372Sfs*22 (on ENST00000269468 / NM_001323950.1; = p.C349Sfs*22 on NM_015845.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 16/81 reads (20%) | called by pindel, varscan2
- MMEL1 | c.678G>C p.Q226H | Missense Mutation (SNP) | VAF 3/11 reads (27%) | SIFT tolerated (0.28); PolyPhen benign (0.013); called by muse, mutect2
- COL5A1 | c.4749G>A p.T1583= | Silent (SNP) | VAF 75/143 reads (52%) | catalogued as rs775725420, COSV65668549, COSV65670309; called by muse, mutect2, varscan2
- GRIK4 | c.1422C>T p.G474= | Silent (SNP) | VAF 43/113 reads (38%) | catalogued as rs144767530, COSV70803287; called by muse, mutect2, varscan2
- PHGDH | c.1173G>A p.V391= | Silent (SNP) | VAF 131/333 reads (39%) | catalogued as rs1325358925, COSV65571249; called by muse, mutect2, varscan2
- TRBV4-2 | c.27G>A p.A9= | Silent (SNP) | VAF 76/563 reads (13%) | catalogued as rs759782974; called by muse, mutect2, varscan2
- VWA7 | c.2256G>A p.S752= | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs144453409; called by mutect2, varscan2
- ZFP57 | c.1284C>T p.V428= | Silent (SNP) | VAF 69/177 reads (39%) | catalogued as COSV65305875, COSV65306329; called by muse, mutect2, varscan2
- ZNF7 | c.1074G>A p.G358= | Silent (SNP) | VAF 18/172 reads (10%) | catalogued as COSV100295847; called by mutect2, varscan2
- AL353804.4 | chrX:73822498 T>C | 5'Flank (SNP) | VAF 445/522 reads (85%) | called by muse, mutect2, varscan2
